Somatic mutation profile of tumor specimen TCGA-73-4668-01A (aliquot TCGA-73-4668-01A-01D-1265-08) from TCGA case TCGA-73-4668, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Invasive micropapillary carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.4 years (24,255 days).
Specimen TCGA-73-4668-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 883c4075-e931-4364-95c4-6ea98243d8e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4668-11A (Solid Tissue Normal), aliquot TCGA-73-4668-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d59dfd97-0cb6-40ac-9aa7-6af76a1830dd

The open-access MAF lists 464 somatic variants for this specimen: 375 protein-altering or splice-affecting, 73 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 315, Silent 73, Nonsense Mutation 33, Frame Shift Del 12, RNA 8, Splice Site 7, Frame Shift Ins 4, Intron 3, 5'UTR 3, Nonstop Mutation 2, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as COSV51709337, COSV99328229; called by muse, mutect2, varscan2
- ABL2 | c.2633G>T p.G878V (on ENST00000502732 / NM_007314.4; = p.G863V on NM_005158.5) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61019198; called by muse, mutect2, varscan2
- ACTN1 | c.2227A>T p.I743F | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV51996077, COSV51998313; called by muse, varscan2
- ADAM22 | c.1109T>C p.L370P | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55986546; called by muse, mutect2, varscan2
- ADAMTS12 | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61259397, COSV61263423; called by muse, mutect2, varscan2
- ADAMTS16 | c.1289C>A p.T430N | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940936; called by muse, mutect2, varscan2
- ADAMTS20 | c.1622G>T p.R541L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV67134638, COSV67137162; called by muse, mutect2, varscan2
- ADAMTS3 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 24/756 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54399257; called by muse, mutect2
- ADAMTSL4 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1411561148, COSV55005156, COSV99647663; called by muse, mutect2, varscan2
- ADCY7 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV54269791; called by muse, mutect2, varscan2
- ADGRB3 | c.1525G>C p.A509P | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV65413638; called by muse, mutect2
- ADGRL4 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.338); catalogued as COSV66064483; called by muse, mutect2, varscan2
- ADH6 | c.1052T>A p.L351Q | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52957363; called by muse, varscan2
- ADNP2 | c.1195G>C p.G399R | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV51541574; called by muse, mutect2, varscan2
- AGAP1 | c.1821C>G p.S607R (on ENST00000304032 / NM_001037131.3; = p.S554R on NM_014914.5) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV58336469; called by muse, mutect2, varscan2
- AGO2 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55051335; called by muse, mutect2, varscan2
- AHI1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs767297135, COSV55623740; called by muse, mutect2
- AMOT | c.3028G>A p.V1010M (on ENST00000371959 / NM_001113490.1; = p.V601M on NM_133265.3) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV59067007; called by muse, mutect2, varscan2
- ANKRD27 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV60134934; called by muse, mutect2, varscan2
- ANKRD36 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 29/251 reads (12%) | catalogued as COSV101347287, COSV70743664; called by muse, mutect2, varscan2
- ANTXR1 | c.382A>T p.S128C | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58019578; called by muse, mutect2, varscan2
- AP3B2 | c.2176G>C p.D726H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.378); catalogued as COSV55612895; called by muse, mutect2, varscan2
- ARRDC3 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs746286312, COSV54366216; called by muse, mutect2, varscan2
- ASTN1 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866932246, COSV56065438, COSV56092745; called by muse, mutect2
- ATIC | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52694858; called by muse, mutect2, varscan2
- ATP10A | c.3119A>T p.Q1040L | Missense Mutation (SNP) | VAF 102/191 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63518235; called by muse, mutect2, varscan2
- ATP6V0D2 | c.550A>T p.K184* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV53416893; called by muse, mutect2, varscan2
- ATP8A2 | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54935014, COSV54970485; called by muse, mutect2, varscan2
- BACH1 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 44/86 reads (51%) | catalogued as COSV99728157; called by muse, mutect2, varscan2
- BCAM | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54304309; called by muse, mutect2, varscan2
- BMPER | c.1958G>T p.G653V | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51828292, COSV51828360; called by muse, mutect2, varscan2
- BPIFA1 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV62823907, COSV62825030; called by muse, varscan2
- C10orf120 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61492478, COSV61492634; called by muse, mutect2, varscan2
- C19orf47 | c.259A>T p.M87L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.343); catalogued as COSV100775064; called by muse, varscan2
- C1QA | c.78C>A p.C26* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV101009965, COSV101009968, COSV101009970; called by muse, mutect2, varscan2
- CACNA1E | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62412211; called by muse, mutect2, varscan2
- CACNA2D3 | c.3149G>A p.R1050K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.049); catalogued as COSV55569083; called by muse, mutect2, varscan2
- CADPS2 | c.3541T>C p.F1181L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57379841; called by muse, mutect2, varscan2
- CARD14 | c.866A>G p.Q289R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV60125967; called by muse, mutect2, varscan2
- CCDC142 | c.959A>T p.N320I | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as COSV99282124; called by muse, mutect2, varscan2
- CDH18 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56909829; called by muse, mutect2
- CDH2 | c.2681T>C p.F894S | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52273285, COSV52292163; called by muse, mutect2, varscan2
- CDH22 | c.825_826insA p.R276Tfs*27 | Frame Shift Ins (INS) | VAF 42/155 reads (27%) | catalogued as COSV100952826; called by mutect2, pindel, varscan2
- CDK6 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56011872; called by muse, mutect2, varscan2
- CEP192 | c.5602G>T p.G1868C | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100381081; called by muse, varscan2
- CEP192 | c.5603G>T p.G1868V | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1056735950, COSV100381085; called by muse, varscan2
- CERS4 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52169505; called by muse, mutect2, varscan2
- CERS6 | c.875G>T p.W292L | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.14); catalogued as COSV59834179; called by muse, mutect2, varscan2
- CFAP300 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 57/183 reads (31%) | catalogued as COSV71570934, COSV71570945; called by muse, mutect2, varscan2
- CFAP47 | c.4467A>T p.G1489= | Splice Region (SNP) | VAF 26/65 reads (40%) | catalogued as COSV57975976; called by muse, mutect2, varscan2
- CFH | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 77/365 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100661455, COSV62777639, COSV62778528; called by muse, mutect2, varscan2
- CFH | c.2573G>T p.W858L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100809436; called by muse, varscan2
- CHAT | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60330684; called by mutect2, varscan2
- CHKA | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55841500; called by muse, mutect2, varscan2
- CHRDL1 | c.1009G>A p.G337R (on ENST00000372045; = p.G343R on NM_145234.4) | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs780795458, COSV54327900; called by muse, mutect2
- CLN6 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV51117762; called by muse, mutect2
- CLTC | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 74/260 reads (28%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.759); catalogued as COSV52251757; called by muse, mutect2, varscan2
- CNGB3 | c.879C>A p.H293Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV60695913; called by muse, mutect2, varscan2
- COL14A1 | c.2753-1G>C p.X918_splice | Splice Site (SNP) | VAF 33/195 reads (17%) | catalogued as COSV52864598; called by muse, mutect2, varscan2
- COL24A1 | c.4031C>A p.P1344Q | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV65311629, COSV65314409; called by muse, mutect2, varscan2
- COL4A4 | c.2590G>T p.G864W | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM053815, CM065090, COSV61630333, COSV61635217; called by muse, mutect2, varscan2
- COQ10B | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV55837307; called by muse, mutect2, varscan2
- CPED1 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100120982, COSV60010187; called by muse, mutect2, varscan2
- CPO | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 53/133 reads (40%) | catalogued as COSV55941139; called by muse, mutect2, varscan2
- CPVL | c.1001C>G p.S334* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as COSV55306833; called by muse, mutect2, varscan2
- CPXM1 | c.1837G>C p.A613P | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV101013829, COSV66045391, COSV66046457; called by muse, mutect2, varscan2
- CROCC | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs760255950, COSV65014287; called by muse, mutect2, varscan2
- CSGALNACT2 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65676231; called by muse, mutect2, varscan2
- CSMD2 | c.5671A>T p.S1891C | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53947751; called by muse, mutect2, varscan2
- CSMD3 | c.6007G>T p.A2003S (on ENST00000297405 / NM_001363185.1; = p.A1899S on NM_052900.3) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); catalogued as COSV52280382, COSV52333172; called by muse, mutect2, varscan2
- CSMD3 | c.2357C>T p.P786L (on ENST00000297405 / NM_001363185.1; = p.P682L on NM_052900.3) | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs150314286; called by muse, mutect2, varscan2
- CSMD3 | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52132305, COSV52280424, COSV99827888; called by muse, mutect2, varscan2
- CTNND2 | c.936C>A p.S312R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV58915370; called by muse, mutect2
- CUL7 | c.3281G>T p.R1094L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99538458, COSV99539089; called by muse, varscan2
- CUL9 | c.240A>T p.L80F | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1355556934, COSV52732818; called by muse, mutect2, varscan2
- CYB5R2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV55086806; called by muse, mutect2
- CYP1A1 | c.1163A>G p.H388R | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765452772, COSV65697954; called by mutect2, varscan2
- CYP2E1 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.431); catalogued as COSV53312897, COSV53314806; called by muse, varscan2
- CYP46A1 | c.396G>T p.E132D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV55896143; called by muse, mutect2, varscan2
- DCAF12L2 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63583736; called by muse, mutect2, varscan2
- DCUN1D4 | c.165C>G p.D55E | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.037); catalogued as COSV58124624; called by muse, mutect2
- DDAH2 | c.535G>T p.G179W | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1356346667, COSV65384324; called by muse, mutect2, varscan2
- DDX53 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60069764; called by muse, mutect2, varscan2
- DEPDC7 | c.936T>A p.S312R (on ENST00000241051 / NM_001077242.2; = p.S303R on NM_139160.2) | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53808753; called by muse, mutect2, varscan2
- DFFB | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58214833; called by muse, mutect2, varscan2
- DISP1 | c.4225C>A p.P1409T | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV52663537, COSV99450558; called by muse, mutect2, varscan2
- DLD | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV52739257; called by muse, mutect2, varscan2
- DMD | c.6121A>T p.I2041L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100821166, COSV63780891; called by muse, varscan2
- DMD | c.2681G>A p.S894N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63775949; called by muse, mutect2, varscan2
- DMXL1 | c.4249G>T p.D1417Y | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60718912; called by muse, mutect2, varscan2
- DNAH11 | c.6208A>T p.I2070F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60973917; called by muse, mutect2, varscan2
- DNAH11 | c.9757C>A p.Q3253K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60973935; called by muse, mutect2, varscan2
- DNAH8 | c.9304G>A p.A3102T | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV59471830; called by muse, mutect2, varscan2
- DNAH9 | c.5706C>A p.Y1902* | Nonsense Mutation (SNP) | VAF 10/107 reads (9%) | catalogued as COSV52369508; called by muse, mutect2
- DNAJC10 | c.987+1G>T p.X329_splice | Splice Site (SNP) | VAF 15/61 reads (25%) | catalogued as COSV51143841; called by muse, mutect2, varscan2
- DNMBP | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV60631051; called by muse, mutect2, varscan2
- DOCK3 | c.2167A>T p.I723F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs763769250, COSV56542083, COSV99810680; called by muse, mutect2, varscan2
- DPP4 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); catalogued as rs1265864737, COSV62108955; called by muse, mutect2, varscan2
- DSC1 | c.1987A>T p.R663* | Nonsense Mutation (SNP) | VAF 88/326 reads (27%) | catalogued as COSV57149863; called by muse, mutect2, varscan2
- DSEL | c.1894G>C p.G632R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59493789; called by muse, mutect2, varscan2
- DSG1 | c.599G>T p.R200I | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV57138452; called by muse, mutect2, varscan2
- EP400 | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 68/350 reads (19%) | catalogued as COSV57782808; called by muse, varscan2
- EPB41L1 | c.1416G>T p.E472D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99150354; called by muse, mutect2
- EPB41L3 | c.2686G>T p.A896S | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV59464378; called by muse, mutect2, varscan2
- EPHA6 | c.562del p.R188Vfs*11 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | catalogued as COSV67571021; called by mutect2, pindel, varscan2
- EPHB1 | c.2305C>A p.L769I | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV67668495; called by muse, mutect2
- EREG | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV55262222; called by muse, mutect2, varscan2
- ESRRG | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63175456; called by muse, mutect2, varscan2
- EXT2 | c.349G>C p.D117H (on ENST00000343631; = p.D150H on NM_000401.3) | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV59153810; called by muse, mutect2, varscan2
- EYS | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60996828; called by muse, mutect2, varscan2
- EZHIP | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57957263; called by muse, mutect2, varscan2
- EZHIP | c.629G>T p.R210M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV57957278; called by muse, mutect2, varscan2
- FAM169A | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 97/192 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV65847066; called by muse, mutect2, varscan2
- FAM47A | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776498294, COSV60499112; called by muse, mutect2, varscan2
- FAM47C | c.2407C>A p.P803T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63729416; called by muse, mutect2, varscan2
- FAM83C | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV65584063; called by muse, mutect2, varscan2
- FCRL1 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV63826800; called by muse, mutect2, varscan2
- FRZB | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54555626; called by muse, mutect2, varscan2
- FSTL5 | c.1933T>A p.Y645N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.279); catalogued as COSV60220091; called by muse, mutect2, varscan2
- GABRA6 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV50889815; called by muse, mutect2
- GDF6 | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.251); catalogued as rs984197099, COSV54626496; called by muse, mutect2, varscan2
- GEN1 | c.1137G>T p.L379F | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV58058093, COSV58058790; called by muse, mutect2, varscan2
- GFUS | c.932G>A p.W311* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55308518; called by muse, mutect2, varscan2
- GINS1 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 32/132 reads (24%) | catalogued as COSV52466090; called by muse, mutect2, varscan2
- GK5 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 27/131 reads (21%) | catalogued as COSV67486543; called by muse, mutect2, varscan2
- GPRC6A | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV59955268; called by muse, mutect2, varscan2
- GRID2 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV56248145; called by muse, mutect2, varscan2
- GRIN2A | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58043725, COSV58051408; called by muse, mutect2, varscan2
- GUCY1B1 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52378071; called by muse, mutect2, varscan2
- H1-3 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55098421; called by muse, mutect2, varscan2
- H2BC13 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 58/167 reads (35%) | catalogued as COSV62440402, COSV62441097; called by muse, mutect2, varscan2
- H4C9 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62890150; called by muse, mutect2, varscan2
- HMCN1 | c.11263G>A p.G3755R | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.661); catalogued as COSV99628204; called by muse, varscan2
- HOXB13 | c.601+1G>T p.X201_splice | Splice Site (SNP) | VAF 49/173 reads (28%) | catalogued as rs763590684, COSV51706752, COSV99285192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRH4 | c.586A>T p.N196Y | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV56929354; called by muse, mutect2, varscan2
- HTR5A | c.894G>T p.W298C | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55284835, COSV55285263; called by muse, mutect2
- HYKK | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 32/56 reads (57%) | catalogued as COSV64762658; called by muse, mutect2, varscan2
- IARS1 | c.3624A>T p.Q1208H | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65116676; called by muse, mutect2, varscan2
- IFFO1 | c.275A>T p.H92L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59112898; called by muse, mutect2, varscan2
- IGF2BP1 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV51734700, COSV99288257; called by muse, mutect2, varscan2
- IGFN1 | c.3278G>T p.R1093L (on ENST00000295591 / NM_001367841.1; = p.R3550L on NM_001164586.2) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV55181338; called by muse, mutect2, varscan2
- IGSF3 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59596640; called by muse, mutect2, varscan2
- ILF3 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51561366; called by muse, mutect2, varscan2
- ILVBL | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs966070250, COSV99654793; called by muse, mutect2, varscan2
- ING4 | c.733G>C p.E245Q (on ENST00000396807 / NM_001127582.2; = p.E244Q on NM_016162.4) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV57523121; called by muse, mutect2, varscan2
- INO80D | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs778476504, COSV68959813; called by muse, mutect2, varscan2
- ITCH | c.964C>T p.P322S (on ENST00000262650 / NM_001257137.3; = p.P281S on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52935649; called by muse, mutect2, varscan2
- ITGA8 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV65234103, COSV65237050; called by muse, mutect2, varscan2
- ITM2A | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV64810589, COSV64811502; called by muse, mutect2, varscan2
- JMJD1C | c.2135C>T p.T712I | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs935797334, COSV67866241; called by muse, mutect2, varscan2
- KCNB1 | c.2056C>G p.P686A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV100870548, COSV65570302; called by muse, mutect2, varscan2
- KCNK18 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV57972782; called by muse, mutect2, varscan2
- KDR | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV55773170; called by muse, mutect2, varscan2
- KIAA1958 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV61726884; called by muse, varscan2
- KIF5B | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV56655245; called by muse, mutect2, varscan2
- KIF6 | c.1099del p.E367Kfs*5 | Frame Shift Del (DEL) | VAF 78/294 reads (27%) | catalogued as COSV54667903; called by mutect2, pindel, varscan2
- KRT6A | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58107078; called by muse, mutect2, varscan2
- L2HGDH | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99910257; called by muse, mutect2, varscan2
- L2HGDH | c.541-1G>T p.X181_splice | Splice Site (SNP) | VAF 20/114 reads (18%) | catalogued as COSV99910258; called by muse, mutect2, varscan2
- LAMP5 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.388); catalogued as COSV55717644; called by muse, mutect2, varscan2
- LARP4 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53326110; called by muse, mutect2, varscan2
- LCE2D | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.011); catalogued as rs761035347, COSV64229171, COSV99056576; called by mutect2, varscan2
- LCT | c.2325C>A p.F775L | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV51555450, COSV99929637; called by muse, varscan2
- LHFPL4 | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as rs76516178, COSV99805450; called by muse, mutect2, varscan2
- LHX4 | c.779-1G>A p.X260_splice | Splice Site (SNP) | VAF 54/195 reads (28%) | catalogued as COSV55377448; called by muse, mutect2, varscan2
- LILRB1 | c.785C>A p.P262Q (on ENST00000427581; = p.P226Q on NM_006669.6) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61120925; called by muse, mutect2, varscan2
- LILRB4 | c.506C>A p.S169* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV54407840; called by muse, mutect2, varscan2
- LINGO2 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100430486; called by muse, mutect2, varscan2
- LINGO2 | c.1789G>T p.G597* | Nonsense Mutation (SNP) | VAF 56/116 reads (48%) | catalogued as COSV100430488, COSV58059464; called by muse, mutect2, varscan2
- LRFN2 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57832699; called by muse, mutect2, varscan2
- LRP1B | c.1089G>T p.R363S | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67195170, COSV67260216; called by muse, mutect2, varscan2
- LTBP2 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.396); catalogued as COSV100001374, COSV56212326; called by muse, mutect2, varscan2
- LUC7L2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.885); catalogued as rs778877438, COSV99692994; called by muse, mutect2, varscan2
- LUM | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99899005; called by muse, mutect2, varscan2
- LYL1 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.224); catalogued as COSV99317071; called by muse, mutect2
- LYZL1 | c.103C>A p.L35M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.714); catalogued as COSV100973624; called by muse, mutect2, varscan2
- MDGA2 | c.1550A>T p.Q517L (on ENST00000399232 / NM_001113498.2; = p.Q219L on NM_182830.4) | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as COSV62109568; called by muse, mutect2, varscan2
- MEI1 | c.3598G>A p.V1200M | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs780439507, COSV55906192; called by muse, mutect2, varscan2
- MIB1 | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV55089069, COSV55093727; called by muse, mutect2, varscan2
- MKLN1 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61762240; called by muse, mutect2, varscan2
- MLF1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 106/173 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs942620752, COSV63034822; called by muse, mutect2, varscan2
- MMRN1 | c.2139A>T p.L713F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV53341392; called by muse, mutect2, varscan2
- MOAP1 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as COSV99365684; called by muse, mutect2, varscan2
- MORN4 | c.275del p.G92Afs*3 | Frame Shift Del (DEL) | VAF 71/168 reads (42%) | catalogued as COSV56730997; called by mutect2, pindel, varscan2
- MPO | c.1076A>T p.Q359L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.123); catalogued as COSV56567563; called by muse, mutect2, varscan2
- MRAP2 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV57634132, COSV57634287; called by muse, mutect2, varscan2
- MUC16 | c.5789G>C p.R1930T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV67456677, COSV67484543; called by muse, varscan2
- NAP1L1 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV53876076; called by muse, mutect2, varscan2
- NAV3 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.02); catalogued as COSV57104008; called by muse, mutect2, varscan2
- NAV3 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV57104034; called by muse, mutect2, varscan2
- NEK11 | c.1176+1G>T p.X392_splice | Splice Site (SNP) | VAF 11/55 reads (20%) | catalogued as COSV63583225; called by muse, mutect2, varscan2
- NFATC1 | c.826C>G p.P276A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV53706975; called by muse, mutect2, varscan2
- NKX6-1 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55685588; called by muse, mutect2, varscan2
- NLRP12 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV60752662; called by muse, varscan2
- NLRP8 | c.2004C>A p.N668K | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52592207; called by muse, varscan2
- NPR1 | c.1021A>C p.M341L | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64143005; called by muse, mutect2, varscan2
- NPY5R | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58451479, COSV58453367, COSV58454350; called by muse, mutect2, varscan2
- NRG3 | c.1201A>T p.N401Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV64578489; called by muse, mutect2
- NRXN1 | c.2437C>A p.R813S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as CM118317, COSV58465691, COSV58481355; called by muse, mutect2, varscan2
- NTNG1 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as COSV53983734; called by muse, varscan2
- NXPH1 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV68318602; called by muse, mutect2, varscan2
- NXPH2 | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV55643232; called by muse, mutect2, varscan2
- OR10A2 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as COSV100225025, COSV56298586; called by muse, mutect2, varscan2
- OR1D5 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73859615; called by muse, mutect2, varscan2
- OR1S2 | c.567C>A p.H189Q | Missense Mutation (SNP) | VAF 102/331 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100224151; called by muse, mutect2, varscan2
- OR2T8 | c.842C>G p.P281R | Missense Mutation (SNP) | VAF 108/293 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100178462, COSV60664253; called by muse, mutect2, varscan2
- OR4C12 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV58860780; called by muse, mutect2, varscan2
- OR4C15 | c.513G>T p.M171I (on ENST00000314644; = p.M117I on NM_001001920.2) | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV58954874; called by muse, mutect2, varscan2
- OR8D1 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100766631; called by muse, mutect2, varscan2
- OR9G1 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV56450650; called by muse, mutect2, varscan2
- P2RY12 | c.613G>T p.V205F | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV56392212; called by muse, mutect2, varscan2
- PCDH18 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV61271330; called by muse, mutect2
- PCDHA11 | c.1316G>C p.R439T | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV56535291; called by muse, varscan2
- PCDHA11 | c.1607C>G p.A536G | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56485376, COSV56535321; called by mutect2, varscan2
- PCDHGA1 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV65298650; called by muse, mutect2, varscan2
- PCDHGA4 | c.1379C>A p.T460N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.662); catalogued as COSV54007581; called by muse, varscan2
- PCDHGB4 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1454704228; called by muse, mutect2, varscan2
- PCLO | c.5362G>T p.E1788* | Nonsense Mutation (SNP) | VAF 55/161 reads (34%) | catalogued as COSV61657874; called by muse, mutect2, varscan2
- PDE6A | c.2315T>A p.L772H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54930433; called by muse, mutect2, varscan2
- PDHA2 | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752911914, COSV54781199; called by muse, mutect2, varscan2
- PEG3 | c.3326G>T p.C1109F | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV55632388, COSV55643660; called by muse, mutect2, varscan2
- PHKB | c.710G>C p.S237T | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54530954; called by muse, mutect2, varscan2
- PHLPP2 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as COSV62426736; called by muse, mutect2, varscan2
- PIK3CB | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56689002; called by muse, mutect2, varscan2
- PJA1 | c.1145G>C p.R382P (on ENST00000361478 / NM_145119.4; = p.R194P on NM_022368.5) | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.324); catalogued as COSV64053629; called by muse, mutect2, varscan2
- PLEKHA6 | c.586A>T p.N196Y | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV55338756; called by muse, mutect2, varscan2
- PLEKHG6 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.45); catalogued as rs201430373, COSV99164161; called by muse, mutect2, varscan2
- PLEKHM1 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV69599324; called by muse, mutect2, varscan2
- PLPPR4 | c.2231C>A p.P744H | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100926780, COSV64565036; called by muse, varscan2
- PLXNA4 | c.5653C>A p.Q1885K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58152543; called by muse, mutect2, varscan2
- POLD1 | c.967A>T p.K323* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV70956764; called by muse, mutect2, varscan2
- POLQ | c.3046G>T p.V1016F | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.226); catalogued as COSV51758911; called by muse, mutect2, varscan2
- PPEF2 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV54425302; called by muse, mutect2, varscan2
- PRMT6 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as rs1359199751, COSV63654983, COSV63656251; called by muse, mutect2, varscan2
- PROKR2 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54087870, COSV54088565; called by muse, mutect2, varscan2
- PRR14 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs780294715, COSV54913305; called by muse, mutect2, varscan2
- PSG1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54955298, COSV54959390; called by muse, mutect2, varscan2
- PTPRU | c.3002A>G p.Y1001C | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60534673; called by muse, mutect2, varscan2
- RALGAPA2 | c.5087G>A p.G1696D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52507366; called by muse, mutect2, varscan2
- RANBP3L | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56957198; called by muse, mutect2, varscan2
- RASGRF2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs376549001, COSV54133822; called by muse, mutect2, varscan2
- RBM39 | c.1237G>T p.A413S (on ENST00000253363 / NM_001323424.2; = p.A407S on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.956); catalogued as COSV53617224; called by muse, varscan2
- RBMX2 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100564758, COSV100564774; called by muse, mutect2, varscan2
- REG1B | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV59307274; called by muse, mutect2, varscan2
- RIF1 | c.4292G>A p.S1431N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV54622163; called by muse, mutect2, varscan2
- RNF220 | c.804+1G>A p.X268_splice | Splice Site (SNP) | VAF 22/115 reads (19%) | catalogued as COSV62408527, COSV62408665; called by muse, varscan2
- RNF38 | c.746A>T p.Q249L | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99424973; called by muse, mutect2, varscan2
- RNF8 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as rs1054331529, COSV100009523, COSV57720497; called by muse, mutect2
- RPL10L | c.644G>T p.*215Lext*? | Nonstop Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100022529; called by muse, mutect2, varscan2
- RPL15 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs554703410, COSV57140781; called by muse, mutect2, varscan2
- RPTOR | c.2780G>T p.R927L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV60805001, COSV60815486; called by muse, mutect2, varscan2
- RSPO1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV100740593, COSV62975066; called by mutect2, varscan2
- RUNX1T1 | c.824G>T p.R275L (on ENST00000265814 / NM_001198628.1; = p.R248L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV56140843, COSV56146054; called by mutect2, varscan2
- RXFP1 | c.689T>C p.M230T | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV57054666; called by muse, mutect2, varscan2
- RYR1 | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as COSV62106919; called by muse, mutect2, varscan2
- RYR1 | c.14260_14261insT p.H4754Lfs*3 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | catalogued as COSV100615505; called by mutect2, pindel, varscan2
- RYR2 | c.5701C>A p.P1901T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as COSV63705805; called by muse, mutect2, varscan2
- RYR2 | c.8674A>G p.I2892V | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.312); catalogued as COSV63705811; called by muse, mutect2, varscan2
- RYR2 | c.12100G>T p.E4034* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV63705818; called by muse, mutect2, varscan2
- RYR3 | c.3661G>T p.G1221C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66804348; called by muse, mutect2, varscan2
- SACS | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66545350; called by muse, mutect2, varscan2
- SEC63 | c.1612C>G p.P538A | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV64601584; called by muse, mutect2, varscan2
- SEMA6A | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57315822, COSV57315953; called by muse, mutect2, varscan2
- SERPINB3 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52193458; called by muse, mutect2, varscan2
- SERPINB8 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54639900, COSV54640412; called by muse, mutect2, varscan2
- SH3D19 | c.2373G>T p.*791Yext*31 | Nonstop Mutation (SNP) | VAF 71/181 reads (39%) | catalogued as COSV58792922; called by muse, mutect2, varscan2
- SI | c.4383G>T p.W1461C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52294599; called by muse, mutect2, varscan2
- SI | c.2319G>T p.W773C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV52294623; called by muse, mutect2, varscan2
- SI | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52294649; called by muse, mutect2, varscan2
- SLC25A6 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67317933; called by mutect2, varscan2
- SLC39A12 | c.873C>A p.F291L | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66197788, COSV66201515; called by muse, mutect2, varscan2
- SLC6A18 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV57253679; called by muse, mutect2, varscan2
- SLC6A9 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.007); catalogued as COSV62211804; called by muse, mutect2
- SLC9A4 | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54837743; called by muse, mutect2, varscan2
- SLIT1 | c.1422C>A p.N474K | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV56596480; called by muse, varscan2
- SLITRK3 | c.1371C>A p.N457K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs768486920, COSV53851832; called by muse, mutect2, varscan2
- SMG1 | c.101G>C p.S34T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV67174085; called by mutect2, varscan2
- SP140 | c.2473C>A p.L825I | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100613690; called by muse, mutect2, varscan2
- SPATA31D1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs778637471, COSV61194563; called by muse, varscan2
- SPATA6 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64062840; called by muse, mutect2
- SPEN | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV65366254; called by muse, mutect2
- SPOPL | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54515463; called by muse, mutect2, varscan2
- SPRYD7 | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100709822, COSV62524050; called by muse, mutect2, varscan2
- SRBD1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV55402626, COSV55403786; called by muse, mutect2, varscan2
- SRMS | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53921943; called by muse, mutect2
- SSTR5 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53513218; called by muse, mutect2, varscan2
- STARD7 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.544); catalogued as rs368914673; called by muse, mutect2, varscan2
- STAT2 | c.163A>T p.K55* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV58476874; called by muse, mutect2, varscan2
- STK31 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63458240; called by muse, mutect2
- STX12 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV100881291; called by muse, mutect2
- STYXL2 | c.1950C>A p.S650R | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV54808833; called by muse, mutect2, varscan2
- SYT11 | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64175687; called by muse, mutect2, varscan2
- SYT4 | c.716A>T p.H239L | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54903260; called by muse, varscan2
- SYT4 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54898595, COSV54903281; called by muse, varscan2
- SYT4 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs1296295606, COSV54903298; called by muse, mutect2, varscan2
- TACR3 | c.1342T>A p.S448T | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV59206809; called by muse, mutect2, varscan2
- TAS2R40 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as COSV101282991; called by muse, mutect2
- TBC1D9 | c.2707G>T p.D903Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV71308352; called by muse, mutect2, varscan2
- TESMIN | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV54834537; called by muse, mutect2, varscan2
- TET3 | c.3160C>T p.R1054C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101327776; called by muse, mutect2, varscan2
- TEX45 | c.551A>T p.Q184L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as rs1191558435, COSV100861805; called by mutect2, varscan2
- TGFBRAP1 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51515040; called by muse, mutect2, varscan2
- TGIF2LX | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as COSV52214908; called by muse, mutect2, varscan2
- THAP5 | c.664C>G p.Q222E (on ENST00000415914 / NM_001130475.3; = p.Q180E on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV99974477; called by muse, mutect2, varscan2
- THNSL2 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59083963, COSV59084283; called by muse, mutect2, varscan2
- TIAM2 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV59701114; called by muse, mutect2, varscan2
- TMEM176A | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV50244193; called by muse, mutect2, varscan2
- TMEM225 | c.486C>A p.C162* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | catalogued as COSV66693905; called by muse, mutect2, varscan2
- TMEM81 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943113112, COSV52706288; called by muse, mutect2, varscan2
- TMTC1 | c.1468G>T p.A490S (on ENST00000539277 / NM_001193451.2; = p.A382S on NM_175861.3) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55490529; called by muse, mutect2, varscan2
- TNR | c.3380C>G p.T1127R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54906515; called by muse, mutect2, varscan2
- TOGARAM1 | c.2270G>C p.C757S | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63894189; called by muse, mutect2, varscan2
- TPH2 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs935519284, COSV61593627; called by muse, varscan2
- TRBV6-1 | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1386088453; called by muse, mutect2, varscan2
- TRDN | c.1361T>A p.V454E | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); catalogued as COSV62130076; called by muse, mutect2, varscan2
- TRIM22 | c.218A>G p.H73R | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs199625192, COSV66091520; called by muse, mutect2, varscan2
- TRIM35 | c.263A>T p.E88V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV57763535; called by muse, mutect2, varscan2
- TRIM42 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs139146415; called by muse, mutect2, varscan2
- TRIM49 | c.1167C>G p.C389W | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as COSV61671637; called by muse, mutect2, varscan2
- TRPM4 | c.1372A>T p.M458L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53267311; called by muse, mutect2, varscan2
- TSPYL5 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1313022537, COSV100438979; called by mutect2, varscan2
- TTN | c.41102C>A p.P13701H (on ENST00000591111; = p.P6277H on NM_003319.4) | Missense Mutation (SNP) | VAF 27/148 reads (18%) | PolyPhen possibly damaging (0.487); catalogued as COSV60264876; called by muse, mutect2, varscan2
- TTN | c.32371A>G p.T10791A (on ENST00000591111; = p.T9864A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | PolyPhen benign (0); catalogued as COSV60264900; called by muse, mutect2, varscan2
- UACA | c.3773G>C p.C1258S | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.213); catalogued as COSV59858530; called by muse, mutect2, varscan2
- UBQLNL | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100974304; called by muse, varscan2
- UBTD2 | c.506G>C p.R169P | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV101196330; called by muse, mutect2, varscan2
- UGT2B17 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497212; called by muse, mutect2, varscan2
- UGT2B28 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 92/232 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59435177; called by muse, varscan2
- UGT2B28 | c.1181C>A p.P394Q | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557930259, COSV100158759, COSV59430976; called by muse, varscan2
- UGT2B4 | c.1559G>T p.R520I | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV59319562; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 20/182 reads (11%) | catalogued as COSV54441319; called by muse, varscan2
- UMOD | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1326292358, COSV56778616; called by muse, mutect2, varscan2
- UNC45B | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52099451; called by muse, mutect2, varscan2
- VENTX | c.623T>A p.V208E | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.328); catalogued as COSV58085167; called by muse, mutect2, varscan2
- VENTX | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58085178; called by muse, mutect2, varscan2
- VPS41 | c.2270G>C p.R757P | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59651974; called by muse, varscan2
- WDFY2 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV53292136; called by muse, mutect2, varscan2
- WDHD1 | c.378C>A p.S126R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV62215206; called by muse, mutect2, varscan2
- XPO6 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100484967, COSV58967008; called by muse, varscan2
- ZC3H13 | c.1642A>T p.R548* | Nonsense Mutation (SNP) | VAF 22/171 reads (13%) | catalogued as COSV54460863; called by muse, mutect2, varscan2
- ZFAT | c.1577A>T p.Q526L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV64744021; called by muse, mutect2, varscan2
- ZGRF1 | c.217G>T p.V73F | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV52202589; called by muse, mutect2, varscan2
- ZMYND8 | c.521A>T p.Q174L (on ENST00000311275 / NM_001363741.2; = p.Q194L on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV53694312; called by muse, mutect2, varscan2
- ZNF148 | c.1460A>T p.Y487F | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as COSV62306880; called by muse, mutect2, varscan2
- ZNF253 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV63038211; called by muse, mutect2, varscan2
- ZNF257 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400263933, COSV71311074; called by muse, mutect2, varscan2
- ZNF415 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV54704042; called by muse, mutect2, varscan2
- ZNF480 | c.1153C>A p.H385N | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.26); catalogued as COSV57997768; called by muse, mutect2, varscan2
- ZNF609 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV58588402; called by muse, mutect2, varscan2
- ZNF793 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454689778, COSV71325144; called by muse, mutect2, varscan2
- ZNF804A | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as rs773636102, COSV56465178; called by muse, mutect2, varscan2
- ZNF831 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV64036909; called by muse, mutect2, varscan2
- ZPLD1 | c.605T>A p.L202* (on ENST00000466937 / NM_001329788.1; = p.L218* on NM_175056.2) | Nonsense Mutation (SNP) | VAF 21/79 reads (27%) | catalogued as COSV60355511; called by muse, mutect2, varscan2
- ZW10 | c.1954G>T p.A652S | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.171); catalogued as COSV99562640; called by muse, varscan2
- ZW10 | c.1953G>T p.K651N | Missense Mutation (SNP) | VAF 85/272 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV99562641; called by muse, varscan2
- ZZEF1 | c.5103G>T p.Q1701H | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as rs763383489, COSV67559603; called by muse, mutect2, varscan2
- CNTNAP3 | c.2791T>C p.C931R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIS3 | c.2828del p.N943Tfs*12 | Frame Shift Del (DEL) | VAF 53/119 reads (45%) | called by mutect2, pindel, varscan2
- DPY19L2 | c.1871del p.L624Yfs*33 | Frame Shift Del (DEL) | VAF 41/141 reads (29%) | called by mutect2, pindel, varscan2
- FEZF1 | c.965del p.G322Afs*10 | Frame Shift Del (DEL) | VAF 50/190 reads (26%) | called by mutect2, pindel, varscan2
- FRG2C | c.722G>T p.W241L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- GTF2IRD2B | c.2686G>T p.G896C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by mutect2, varscan2
- IL27 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2
- IWS1 | c.1299del p.K434Rfs*3 | Frame Shift Del (DEL) | VAF 81/216 reads (38%) | called by mutect2, pindel, varscan2
- LPA | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 100/1869 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); called by muse, mutect2
- MTARC2 | c.892del p.L298Cfs*28 | Frame Shift Del (DEL) | VAF 50/268 reads (19%) | called by pindel, varscan2
- RP1L1 | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- SPEN | c.6884del p.P2295Qfs*58 | Frame Shift Del (DEL) | VAF 26/180 reads (14%) | called by mutect2, pindel, varscan2
- TENT4A | c.1848dup p.G617Wfs*3 | Frame Shift Ins (INS) | VAF 34/188 reads (18%) | called by mutect2, pindel, varscan2
- TKTL2 | c.1253dup p.S419Ffs*36 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- TMEM132E | c.2190del p.T731Lfs*64 (on ENST00000321639; = p.T821Lfs*64 on NM_001304438.2) | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, varscan2
- TRPV3 | c.2337del p.F779Lfs*50 | Frame Shift Del (DEL) | VAF 56/101 reads (55%) | called by mutect2, pindel, varscan2
- ZC3HAV1 | c.1948del p.V650Cfs*12 | Frame Shift Del (DEL) | VAF 52/191 reads (27%) | called by mutect2, pindel, varscan2
- ZNF169 | c.1787_1789del p.Q596del | In Frame Del (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel
- ZNF658 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- ACE | c.2037C>T p.T679= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs775205401, COSV52011796; called by muse, mutect2, varscan2
- ADAMTS16 | c.1290C>A p.T430= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV57004949, COSV99940939; called by muse, mutect2, varscan2
- ADAMTS18 | c.903A>T p.A301= | Silent (SNP) | VAF 60/225 reads (27%) | catalogued as COSV51421148; called by muse, mutect2, varscan2
- ARHGAP31 | c.2988T>A p.I996= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV51797407; called by muse, mutect2, varscan2
- ARHGEF15 | c.1785C>A p.I595= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV62724633, COSV62725454; called by mutect2, varscan2
- CACNA1I | c.4440C>A p.I1480= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV60814228, COSV60819784; called by muse, mutect2, varscan2
- CFH | c.381T>C p.R127= | Silent (SNP) | VAF 22/279 reads (8%) | catalogued as COSV62778527; called by muse, mutect2
- CFLAR | c.1264C>T p.L422= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1559250637, COSV58581661; called by muse, mutect2, varscan2
- CNTNAP4 | c.621T>A p.I207= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV56695565; called by muse, mutect2, varscan2
- CRIP3 | c.411G>T p.V137= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV99240301; called by muse, mutect2, varscan2
- DCPS | c.954C>G p.T318= | Silent (SNP) | VAF 23/344 reads (7%) | catalogued as COSV55012072; called by muse, mutect2
- DENND1B | c.135A>G p.L45= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52470652; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.534A>T p.T178= | Silent (SNP) | VAF 51/106 reads (48%) | catalogued as COSV50052698; called by muse, mutect2, varscan2
- EIF5B | c.39C>T p.T13= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV56815971; called by muse, mutect2, varscan2
- ERGIC2 | c.36G>A p.L12= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV64113088; called by muse, varscan2
- FAT3 | c.12907C>A p.R4303= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV53089047, COSV53158146; called by mutect2, varscan2
- FCAMR | c.462C>A p.T154= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV100249415; called by muse, mutect2, varscan2
- GRIK3 | c.1962G>T p.T654= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100902284, COSV66145034; called by muse, mutect2, varscan2
- HMCN1 | c.11262T>A p.A3754= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as COSV99628200; called by muse, varscan2
- IL1RAP | c.891C>T p.T297= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as COSV50767758; called by muse, mutect2, varscan2
- IRS1 | c.2619G>T p.R873= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV59338947; called by muse, mutect2, varscan2
- KANSL1 | c.3243G>T p.S1081= (on ENST00000574590 / NM_001193465.2; = p.S1082= on NM_015443.4) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV52238530, COSV52245730; called by muse, mutect2, varscan2
- KCTD8 | c.1140A>T p.T380= | Silent (SNP) | VAF 97/185 reads (52%) | catalogued as COSV63594229; called by muse, mutect2, varscan2
- LAMA5 | c.7332G>T p.L2444= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV53368981; called by muse, mutect2, varscan2
- LAMB4 | c.3675T>A p.S1225= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV52727720; called by muse, mutect2, varscan2
- LRP1B | c.4122A>T p.A1374= | Silent (SNP) | VAF 68/174 reads (39%) | catalogued as COSV67260215; called by muse, mutect2, varscan2
- LRRC37B | c.2694A>G p.P898= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV58954147; called by muse, mutect2, varscan2
- MAP3K7 | c.1119G>T p.G373= | Silent (SNP) | VAF 69/276 reads (25%) | catalogued as COSV100997484; called by muse, varscan2
- MC3R | c.114C>A p.V38= | Silent (SNP) | VAF 69/199 reads (35%) | catalogued as COSV54763156, COSV54764184; called by muse, varscan2
- MCTP1 | c.1302G>A p.L434= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV56528910; called by muse, mutect2, varscan2
- MIA3 | c.3255G>A p.L1085= | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as COSV60516419; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1914C>T p.L638= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as COSV64057179; called by muse, mutect2, varscan2
- NKX2-2 | c.42C>T p.D14= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV65820115, COSV65820179; called by muse, mutect2, varscan2
- NLRC3 | c.1173T>C p.H391= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs763376473, COSV57094411; called by muse, mutect2, varscan2
- NOC2L | c.1257G>C p.L419= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV58990246; called by muse, mutect2, varscan2
- OR10G7 | c.561C>A p.A187= | Silent (SNP) | VAF 122/440 reads (28%) | catalogued as COSV57868348; called by muse, mutect2, varscan2
- OR4C46 | c.558C>A p.A186= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as rs753222627, COSV60220769; called by muse, mutect2, varscan2
- OR51G1 | c.75C>A p.L25= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV58970320; called by muse, mutect2, varscan2
- PCDHB7 | c.1443C>A p.G481= | Silent (SNP) | VAF 44/84 reads (52%) | catalogued as rs1400343681, COSV50783124, COSV50803381; called by muse, mutect2
- PKHD1 | c.3249G>T p.V1083= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV61890243; called by muse, mutect2, varscan2
- PLS3 | c.915T>A p.L305= | Silent (SNP) | VAF 50/158 reads (32%) | catalogued as COSV56781274; called by muse, mutect2, varscan2
- POLR2B | c.216G>A p.Q72= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV58902204; called by muse, mutect2, varscan2
- PRPF31 | c.882G>T p.L294= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV58086599; called by muse, mutect2
- PRSS1 | c.210G>A p.Q70= | Silent (SNP) | VAF 39/255 reads (15%) | catalogued as COSV61196172; called by muse, mutect2, varscan2
- PSMD4 | c.465C>T p.A155= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as rs769012730, COSV64393914; called by muse, mutect2, varscan2
- RET | c.1884A>G p.P628= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs786202671, COSV60704460; called by muse, mutect2, varscan2
- RIPOR1 | c.744T>C p.S248= (on ENST00000379312 / NM_001193522.2; = p.S244= on NM_024519.4) | Silent (SNP) | VAF 81/202 reads (40%) | catalogued as COSV50247061; called by muse, mutect2, varscan2
- RP1L1 | c.1419C>G p.P473= | Silent (SNP) | VAF 34/78 reads (44%) | called by muse, varscan2
- RXFP4 | c.249G>A p.L83= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs920168398, COSV58149298; called by mutect2, varscan2
- SINHCAF | c.567A>G p.T189= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100530550; called by muse, mutect2, varscan2
- SLC15A3 | c.873G>A p.L291= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV57172990; called by muse, mutect2, varscan2
- SLC2A9 | c.69C>T p.H23= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs749006941, COSV53326253; called by muse, mutect2, varscan2
- SPOCK2 | c.816C>T p.A272= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs1227956174, COSV58037945; called by muse, mutect2, varscan2
- SRRM2 | c.1959T>C p.A653= | Silent (SNP) | VAF 39/183 reads (21%) | catalogued as rs537620426, COSV57079044; called by muse, mutect2, varscan2
- STX16 | c.429G>T p.L143= (on ENST00000371141 / NM_001001433.3; = p.L122= on NM_003763.6) | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV56607549; called by mutect2, varscan2
- STYXL2 | c.639G>T p.A213= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs573463190, COSV54808823, COSV99608432; called by muse, mutect2, varscan2
- TENM1 | c.1602C>T p.T534= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100949829; called by muse, mutect2, varscan2
- TENM3 | c.4257T>A p.T1419= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV69315945; called by muse, mutect2, varscan2
- THSD1 | c.921G>A p.L307= | Silent (SNP) | VAF 53/113 reads (47%) | catalogued as rs1388049617, COSV51630843; called by muse, mutect2, varscan2
- TIE1 | c.2604C>A p.A868= | Silent (SNP) | VAF 60/127 reads (47%) | catalogued as COSV65250941; called by muse, mutect2, varscan2
- TMEM123 | c.12C>T p.G4= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV63444384; called by muse, mutect2, varscan2
- TMEM229B | c.12C>G p.A4= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100664302; called by muse, mutect2, varscan2
- TNFRSF11A | c.1677G>C p.A559= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54023859, COSV54026995, COSV99500186; called by mutect2, varscan2
- TTN | c.100866C>A p.A33622= (on ENST00000591111; = p.A26198= on NM_003319.4) | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV60264849; called by muse, mutect2, varscan2
- UBE4B | c.1137A>G p.L379= | Silent (SNP) | VAF 22/231 reads (10%) | catalogued as rs1327691197, COSV53539697; called by muse, mutect2, varscan2
- UBTD2 | c.507C>A p.R169= | Silent (SNP) | VAF 73/143 reads (51%) | catalogued as COSV101196328; called by muse, mutect2, varscan2
- UCHL5 | c.369A>T p.A123= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV66486906; called by muse, mutect2, varscan2
- UNC45B | c.486C>A p.L162= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV52099435; called by muse, mutect2, varscan2
- WDR59 | c.1968G>T p.L656= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV50941881; called by muse, mutect2, varscan2
- ZAN | c.1884C>A p.I628= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV61804779, COSV61813904; called by muse, mutect2, varscan2
- ZNF668 | c.1668G>T p.R556= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV56217933; called by muse, mutect2, varscan2
- ZNF761 | c.438G>A p.S146= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs758595093, COSV61889244; called by muse, mutect2
- ZNF98 | c.1488C>G p.G496= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs74169609, COSV63338812; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848060 G>T | 5'Flank (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- CCDC70 | c.-22G>A | 5'UTR (SNP) | VAF 14/72 reads (19%) | catalogued as rs369776694; called by muse, mutect2, varscan2
- CD300LD | c.-21G>A | 5'UTR (SNP) | VAF 33/93 reads (35%) | catalogued as rs1304122782, COSV60084423; called by muse, mutect2, varscan2
- FXYD6-FXYD2 | c.210-535C>A | Intron (SNP) | VAF 40/113 reads (35%) | catalogued as COSV52804926; called by muse, mutect2, varscan2
- LPAL2 | n.303C>A | RNA (SNP) | VAF 35/162 reads (22%) | called by muse, mutect2, varscan2
- MIR516A2 | n.7G>A | RNA (SNP) | VAF 52/156 reads (33%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-2829G>T | Intron (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- NFYC | c.388-802C>G | Intron (SNP) | VAF 21/58 reads (36%) | catalogued as COSV58125463; called by muse, mutect2, varscan2
- OR2W5 | n.459C>A | RNA (SNP) | VAF 72/140 reads (51%) | called by muse, mutect2, varscan2
- REXO1L1P | n.771C>A | RNA (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- RN7SL484P | chr15:99790979 T>C | 5'Flank (SNP) | VAF 85/154 reads (55%) | called by muse, mutect2, varscan2
- SNORD113-3 | n.54C>T | RNA (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- SNORD114-3 | n.69G>T | RNA (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- TCP10L3 | n.477G>T | RNA (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100833082; called by mutect2, varscan2
- TUBB7P | n.1182C>A | RNA (SNP) | VAF 69/194 reads (36%) | called by muse, mutect2, varscan2
- UCHL5 | c.-217C>A | 5'UTR (SNP) | VAF 9/23 reads (39%) | catalogued as rs747836649, COSV100814617; called by muse, mutect2, varscan2
